Surgical pathology report (de-identified scan), TCGA case TCGA-4G-AAZO, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Sapienza University of Rome, specimen TCGA-4G-AAZO-01A (Primary Tumor).

pathology report

10A-0-3
Cholangiocarcinoma 8/60/3
Site: intrahepatic bile duct c22.1
lw
4/23/14

Date of tumor procurement:

Anatomic site: intrahepatic

Histology diagnosis: moderately differentiated intrahepatic cholangiocarcinoma

Immunohistochemistry: CK7 and CK19 positive, CK20 and CDX-2 and TTF1 negative

Immunohistochemistry: CK7 positive, CK20 and TTF1 negative

Histological examination

Right liver + segment 4: hepatic resection of 17x12x10 cm, characterized by the presence of a whitish nodule of 10 cm lapping the margin of resection. Histological, it is a moderately differentiated adenocarcinoma lesion with an immunohistochemical profile consistent, albeit in a nonspecific and non-exclusive, with intrahepatic cholangiocarcinoma with positivity for Cytokeratins 7 and 19 and negativity for Cytokeratin 20, CDX-2, and TTF1. The liver tissue shows steatosis (5%), mild fibrosis (1-2/6 Ishak)

- Lymph node hepatic peduncle (2): reactive lymphadenitis

Source: NCI Genomic Data Commons file b1bea736-3d35-414c-af9c-2c354713495d (TCGA-4G-AAZO.C6A65949-C248-4729-B41F-9C65A46A7AF7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).